MMRF case MMRF_1281 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/5bde0059-5b21-4696-bacd-825c2f489996

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 37 years; Vital status: Dead; Days to death: 153 days; Cause of death: Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 37.3 years (13,638 days); ISS stage: III; Days to last known disease status: 153 days; Days to last follow up: 153 days.
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 153 days.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 153.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -4 (ECOG 2): M Protein 7.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 175 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.06 mg/dL; Immunoglobulin G 94.6 g/L; Immunoglobulin A 0.57 g/L; Immunoglobulin M 0.23 g/L; Beta 2 Microglobulin 8.9 µg/mL; Lactate Dehydrogenase 13.9 µkat/L; Hemoglobin 4.46 mmol/L; Leukocytes 6 ×10⁹/L; Absolute Neutrophil 4.26 ×10⁹/L; Platelets 165 ×10⁹/L; Creatinine 186 µmol/L; Blood Urea Nitrogen 15.4 mmol/L; Calcium 1.93 mmol/L; Albumin 25 g/L; Total Protein 12.9 g/dL; Glucose 5.45 mmol/L; C-Reactive Protein 2.2 mg/dL.
- Day 76 (ECOG 2): M Protein 2.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 24.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.22 mg/dL; Immunoglobulin G 27.9 g/L; Immunoglobulin A 0.96 g/L; Immunoglobulin M 0.28 g/L; Lactate Dehydrogenase 22 µkat/L; Hemoglobin 6.39 mmol/L; Leukocytes 6.6 ×10⁹/L; Absolute Neutrophil 5.07 ×10⁹/L; Platelets 156 ×10⁹/L; Creatinine 354 µmol/L; Blood Urea Nitrogen 43.9 mmol/L; Calcium 2.05 mmol/L; Albumin 38 g/L; Total Protein 8.4 g/dL; Glucose 5.72 mmol/L.

Other clinical attributes
- Day -4: Weight: 80 kg; Height: 161 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1281_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -4 days.
- Sample MMRF_1281_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -4 days.
